MMRF case MMRF_1970 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/9cb60de9-3a22-4016-944a-68d5523c4e67

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 69 years; Vital status: Dead; Days to death: 259 days; Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 69.9 years (25,525 days); ISS stage: II; Days to last known disease status: 259 days; Days to last follow up: 259 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 176 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 148 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 259.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 0): M Protein 2.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 25.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.35 mg/dL; Beta 2 Microglobulin 5.07 µg/mL; Hemoglobin 8.12 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 147 ×10⁹/L; Creatinine 177 µmol/L; Blood Urea Nitrogen 13.6 mmol/L; Calcium 2.23 mmol/L; Albumin 27 g/L; Total Protein 9.1 g/dL; Glucose 6.99 mmol/L.
- Day 85 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 22.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.48 mg/dL; Hemoglobin 8.74 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 129 ×10⁹/L; Creatinine 186 µmol/L; Blood Urea Nitrogen 13.2 mmol/L; Calcium 2.28 mmol/L; Albumin 31 g/L; Total Protein 7.6 g/dL; Glucose 8.64 mmol/L.
- Day 162 (ECOG 0): M Protein 1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 14.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.24 mg/dL; Hemoglobin 9.24 mmol/L; Leukocytes 7.1 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 148 ×10⁹/L; Creatinine 168 µmol/L; Blood Urea Nitrogen 11.1 mmol/L; Calcium 2.25 mmol/L; Albumin 29 g/L; Total Protein 7.6 g/dL; Glucose 8.53 mmol/L.

Other clinical attributes
- Day 1: Weight: 114 kg; Height: 188 cm.

Biospecimens (2 samples)
- Sample MMRF_1970_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_1970_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
